Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A3G6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A3G6-01A (Primary Tumor).

[page 1 of 4]
Histology

* Final Report *

Result Type: Histology
Result Date:
Result Status:
Result Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

Patient Name: [REDACTED] Lab Accession #:
Patient DOB: [REDACTED] Collection Date:
Accession Date: [REDACTED]
Sign Out Date: [REDACTED]

Tissue Source:
1: UTERUS, CERVIX, TUBES, OVARIES FOR FS AND NORMAL SKIN
2: RIGHT PELVIC NODES
3: LEFT PELVIC NODES
4: PERIAORTIC NODES

Final Diagnosis:
Parts 1 through 4.
Uterus, cervix, bilateral ovaries, bilateral fallopian tubes and lymph nodes (right and left pelvic and periaortic); hysterectomy, bilateral salpingo-oophorectomy and lymphadenectomy:

- Uterine papillary serous carcinoma.

A. Tumor Grade: III.

- Myometrium:

- A. Depth of myometrial invasion: 30%.
- B. Lymphatic invasion: Not identified.
- C. Blood vessel invasion: Not identified.
- D. Additional findings:
- A. Leiomyoma.
- B. Adenomyosis.

- Cervix: Chronic cervicitis.

- Ovaries:

- A. Right: No histopathologic change.
- Other: Endometriosis, paraovarian.

Printed by:
Printed on:

	lu 11/29/11	

1CD-0-3

adenocarcinoma, serous, NOS 8441/3

Site: endometrium c54.1

lu 11/29/11

[page 2 of 4]
Histology

* Final Report *

- B. Left: No histopathologic change.
- **Fallopian Tubes:**
- A. Right: No histopathologic change.
Other: Endometriosis, paratubal.
- B. Left: Walthard nests.
- **Margins of Excision:** Margins are free of tumor.
- **Lymph Nodes, right pelvic (part 2):**
- A. Number examined: 5.
- B. Number positive: 0.
- **Lymph Nodes, left pelvic (part 3):**
- A. Number examined: 6.
- B. Number positive: 0.
- **Lymph Nodes, paraortic (part 4):**
- A. Number examined: 5.
- B. Number positive: 0.
- **Additional Findings and Comments:**
- A. Immunohistochemical studies are performed; the results are as follows:
- A. p16: Positive in tumor cells, strong nuclear and cytoplasmic staining, diffuse.
- Interpretation: The above result supports the morphologic diagnosis of papillary serous carcinoma.
- **pTNM Stage (AJCC 7th edition 2010):**
- A. Primary tumor: pT1a.
- B. Regional lymph nodes: pN0.
- C. Distant metastasis: pMX.

Comment:

These immunohistochemistry and/or in-situ hybridization tests were developed and their performance characteristics determined by the immunohistochemistry and in-situ hybridization laboratories at _____ they may not have been cleared or approved by the U.S. Food and Drug Administration (FDA). However, the FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research.

Intraoperative Consult Diagnosis:

Part 1.

Frozen section diagnosis:

- Uterus, cervix, bilateral fallopian tubes and ovaries (FSx1):
- Endometrioid adenocarcinoma, high grade, with squamous differentiation.
- Tumor invades less than 50% of the myometrial thickness.

Dr. _____

Gross Description:

Part 1.

A. Specimen Identification:

Printed by:
Printed on:

[page 3 of 4]
Histology

* Final Report *

1. Received labelled as "Uterus, cervix, tubes and ovaries".
2. Received fresh in the frozen section room.
3. Type of specimen: Uterus with cervix and bilateral tubes and ovaries.
- B. **Weight Of Specimen:** 0.02 kg.
- C. **Uterine Corpus:**
1. Size: 4.7 cm (superior-inferior length) x 3.5 cm (cornu-cornu width) x 1.5 cm (anterior-posterior diameter).
2. Shape: Asymmetrical.
- D. **Serosa:**
1. Appearance: Smooth.
- E. **Cervix:**
1. Length of cervix: 2.1 cm.
2. Diameters of ectocervix: 2.9 cm (3-9 o'clock) x 1.8 cm (12-6 o'clock).
3. Appearance of ectocervical mucosa: Tan-pink with petechiae.
4. Size of external os: 0.4 x 0.2 cm.
Shape: Slit-like.
Patency: Patent.
5. Appearance of endocervical mucosa: Glistening, and tan-pink.
- F. **Endometrium/Tumor:**
1. Size of endometrial cavity: 1.8 x 3.5 cm.
Shape: Triangular.
2. Comment: No gross tumor is seen. An area of irregularity was identified on the posterior endometrium and submitted for frozen section.
- G. **Myometrium:**
1. Thickness: 1.8 cm.
2. Appearance: Homogenous.
- H. **Adnexa(e):**
1. Fallopian Tubes:
- A. Right: 5.4 x 1.2 x 0.7 cm.
Lumen: Patent.
- B. Left: 5.8 x 0.8 x 0.6 cm.
Lumen: Patent.
- C. Comment: Fimbriated. No adhesions. One paratubal cyst measuring 0.4 x 0.4 x 0.2 cm was noted on the left fallopian tube.
2. Ovaries:
- A. Right: 2.7 x 0.9 x 0.8 cm.
Capsule: Smooth. No papillations or adhesions.
Stroma: One cystic area noted measuring 0.3 x 0.2 x 0.2 cm.
- B. Left: 2.0 x 1.7 x 0.5 cm.
Capsule: Smooth. No papillations or adhesions.
Stroma: No cysts noted.
- I. **Lymph Node Examination:** Not sent.
- J. **Intraoperative Diagnosis:**
1. Requested: Yes.
2. Performed: Yes.
3. Type: Frozen section.
- K. **Additional Tissue Processing:** None.
- L. **Summary of Sections (specify):**
- 1 - frozen section, 1 piece
- 2 - 12 o'clock cervix, 1 piece
- 3 - 6 o'clock cervix, 1 piece

[page 4 of 4]
Histology

* Final Report *

- 4 – anterior lower uterine segment, 1 piece
- 5 – posterior lower uterine segment, 1 piece
- 6 through 10 – anterior endometrium and myometrium, 1 piece each
- 11 through 14 – posterior endometrium and myometrium, 1 piece each
- 15 – right fallopian tube, 4 pieces, embed on end
- 16 – right ovary, 2 pieces
- 17 – left fallopian tube, 4 pieces, embed on end
- 18 – left ovary, 2 pieces
- 19 – left paratubal cyst, 2 pieces. [REDACTED]

Part 2. Labelled "right pelvic nodes". 2.1 x 1.8 x 0.3 cm. The specimens are serially sectioned and submitted entirely.

- 1 – one lymph node, 2 pieces
- 2 – one lymph node, 1 piece
- 3 – one lymph node, 3 pieces
- 4 & 5 – one lymph node, 3 pieces and 2 pieces respectively
- 6 & 7 – one lymph node, 2 pieces each. [REDACTED]

Part 3. Labelled "left pelvic nodes". Received in formalin are multiple tan-pink, fibrous tissue fragments measuring from 0.4 x 0.3 x 0.3 cm to 2.8 x 0.9 x 0.3 cm. The specimens are serially sectioned and submitted entirely.

- 1 – one lymph node, 1 piece
- 2 – one lymph node, 3 pieces
- 3 & 4 – one lymph node, 2 pieces each
- 5 – one lymph node, 3 pieces
- 6 & 7 – one lymph node, 3 pieces each
- 8 & 9 – one lymph node, 3 pieces and 2 pieces respectively. [REDACTED]

Part 4. Labelled "periaortic nodes". Received in formalin are three brown-tan, fibroadipose tissue fragments measuring 1.0 x 0.7 x 0.3 cm, 1.8 x 0.5 x 0.3 cm and 3.8 x 1.7 x 0.4 cm. The specimens are serially sectioned and submitted entirely.

- 1 – one lymph node, 4 pieces
- 2 & 3 – one lymph node, 3 pieces and 2 pieces respectively
- 4 – one lymph node, 2 pieces
- 5 & 6 – one lymph node, 3 pieces and 2 pieces respectively
- 7 & 8 – one lymph node, 3 pieces each. [REDACTED]

Primary Pathologist:

Completed Action List:

Source: NCI Genomic Data Commons file b769e969-7371-4e32-9f4f-de5416e7b082 (TCGA-AX-A3G6.53586ED5-5C68-4517-8543-7508AF37F68C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).